Somatic mutation profile of tumor specimen TCGA-60-2710-01A (aliquot TCGA-60-2710-01A-01W-0877-08) from TCGA case TCGA-60-2710, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.5 years (24,669 days).
Specimen TCGA-60-2710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faadc287-5430-445a-b416-b89c7f03cd32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2710-11A (Solid Tissue Normal), aliquot TCGA-60-2710-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fd01021-309e-4e3e-930b-7ead20ff0ea2

The open-access MAF lists 203 somatic variants for this specimen: 162 protein-altering or splice-affecting, 40 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 40, Nonsense Mutation 9, Splice Site 5, Frame Shift Ins 4, Frame Shift Del 4, In Frame Del 1, Nonstop Mutation 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.870G>C p.W290C | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918499, CM970527, CM970528, COSV60643917; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 104/212 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs942306533, COSV60695342; called by muse, mutect2, varscan2
- ABCD1 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs782158792, CM044845, COSV54388211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD10 | c.332A>T p.D111V | Missense Mutation (SNP) | VAF 117/255 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56326578; called by muse, mutect2, varscan2
- ABHD4 | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV53530947; called by muse, mutect2, varscan2
- ADHFE1 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.371); catalogued as COSV52559855; called by muse, mutect2, varscan2
- AKAP17A | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs756733838, COSV58312497; called by muse, mutect2, varscan2
- ALG13 | c.3170C>A p.S1057Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV52646117; called by muse, mutect2, varscan2
- AMBRA1 | c.3749C>A p.S1250Y (on ENST00000458649 / NM_001367468.1; = p.S1160Y on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV54064076; called by muse, mutect2, varscan2
- AMHR2 | c.1390C>G p.P464A | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57687353; called by muse, mutect2, varscan2
- AMMECR1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as COSV53321132; called by muse, mutect2, varscan2
- ARHGEF10L | c.943-1G>T p.X315_splice | Splice Site (SNP) | VAF 26/112 reads (23%) | catalogued as COSV51442740; called by muse, varscan2
- ARMCX2 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV57531345; called by muse, mutect2, varscan2
- ASIC2 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV63331474; called by muse, mutect2, varscan2
- ASIC3 | c.216C>A p.H72Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52511692; called by muse, varscan2
- ATP10D | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561130132, COSV56703624; called by muse, mutect2, varscan2
- ATP13A5 | c.2374T>C p.C792R | Missense Mutation (SNP) | VAF 50/505 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs760725199, COSV60871826; called by muse, mutect2, varscan2
- BCAP31 | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54383685; called by muse, mutect2, varscan2
- BCL9L | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1352185829, COSV52690156; called by muse, mutect2, varscan2
- BORA | c.1669G>A p.E557K (on ENST00000613797; = p.E482K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/513 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64696050; called by muse, mutect2, varscan2
- BRWD3 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV64754581; called by muse, mutect2, varscan2
- BUB1 | c.1922G>T p.C641F | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57067928; called by muse, mutect2, varscan2
- C3orf38 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59629092; called by muse, mutect2, varscan2
- CA11 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV50034516; called by muse, mutect2, varscan2
- CC2D1B | c.84G>C p.M28I | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52563538; called by muse, mutect2, varscan2
- CCDC105 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as rs753056711, COSV52965974; called by muse, mutect2, varscan2
- CCDC170 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 164/490 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV53347482; called by muse, mutect2, varscan2
- CDC7 | c.1724G>T p.*575Lext*1 | Nonstop Mutation (SNP) | VAF 39/170 reads (23%) | catalogued as COSV52313164; called by muse, mutect2, varscan2
- CDK5RAP3 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs368942321; called by muse, varscan2
- CDKL5 | c.3036G>T p.Q1012H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV66107717; called by muse, mutect2, varscan2
- CDKL5 | c.3037G>T p.V1013L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV66107723; called by muse, mutect2, varscan2
- CELF4 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV58467729; called by muse, mutect2, varscan2
- CEP152 | c.1543A>G p.K515E | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV57866231; called by muse, mutect2, varscan2
- CHGB | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs368972632; called by muse, mutect2, varscan2
- CLINT1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.31); catalogued as COSV51630033; called by muse, mutect2, varscan2
- COL1A1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV56810076; called by muse, mutect2, varscan2
- COL4A1 | c.3685C>A p.H1229N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.835); catalogued as COSV65432746; called by muse, mutect2, varscan2
- COL4A2 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64635152; called by muse, mutect2, varscan2
- COL4A4 | c.4325G>T p.G1442V | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637218; called by muse, mutect2, varscan2
- COLEC11 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV52598439; called by muse, mutect2, varscan2
- CPXCR1 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 31/167 reads (19%) | catalogued as rs922613625, COSV52164922; called by muse, mutect2, varscan2
- CRB1 | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.799); catalogued as COSV66350228; called by muse, mutect2, varscan2
- CSMD3 | c.3281C>A p.T1094K (on ENST00000297405 / NM_001363185.1; = p.T990K on NM_052900.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV52158763; called by muse, mutect2, varscan2
- CYB5R4 | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774440809, COSV63752629; called by muse, mutect2, varscan2
- DAB1 | c.1162C>T p.P388S (on ENST00000371231; = p.P355S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV100976722, COSV64691995; called by muse, mutect2, varscan2
- DMRT1 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs766842219, COSV66524916; called by muse, varscan2
- EEF1AKNMT | c.597G>T p.Q199H (on ENST00000361735 / NM_015935.5; = p.Q113H on NM_014955.3) | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as COSV62283939; called by muse, mutect2, varscan2
- EIF4E3 | c.352G>T p.E118* (on ENST00000425534 / NM_001134651.2; = p.E12* on NM_173359.5) | Nonsense Mutation (SNP) | VAF 40/72 reads (56%) | catalogued as COSV55207327; called by muse, mutect2, varscan2
- EPHA3 | c.2275G>T p.V759L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs146856660, COSV60730088; called by muse, mutect2, varscan2
- EPHA6 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 254/1510 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs780254423, COSV67598252; called by muse, mutect2, varscan2
- EVC2 | c.3176A>G p.N1059S | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60405192; called by muse, mutect2, varscan2
- FAM120B | c.1719C>G p.D573E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV53009269; called by muse, mutect2, varscan2
- FBXL7 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61654872; called by muse, mutect2, varscan2
- FILIP1L | c.2247dup p.L750Tfs*16 (on ENST00000354552 / NM_182909.3; = p.L510Tfs*16 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 90/628 reads (14%) | catalogued as rs1433753279; called by mutect2, varscan2
- FSTL5 | c.767G>T p.S256I | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV60238057; called by muse, mutect2, varscan2
- GBA | c.205A>C p.T69P | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59171242; called by muse, mutect2, varscan2
- GDAP2 | c.1276T>G p.F426V | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV65613591; called by muse, mutect2, varscan2
- GPM6A | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV54531787, COSV54565099; called by muse, mutect2, varscan2
- HDC | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51085364; called by muse, mutect2, varscan2
- HEPH | c.718C>A p.H240N (on ENST00000343002; = p.H294N on NM_138737.5) | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1456888736, COSV57973476; called by muse, mutect2, varscan2
- HIVEP1 | c.6682A>T p.T2228S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV65105478; called by muse, mutect2, varscan2
- HMMR | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.327); catalogued as COSV62375645; called by muse, mutect2, varscan2
- HSCB | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV53263569; called by muse, mutect2, varscan2
- HUWE1 | c.10715T>A p.V3572E | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as COSV53367705; called by muse, mutect2, varscan2
- IFFO1 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60739674; called by muse, mutect2, varscan2
- IGSF1 | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 49/227 reads (22%) | catalogued as COSV63841040; called by muse, mutect2, varscan2
- IL1RAPL1 | c.978A>C p.E326D | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV56310003; called by muse, mutect2, varscan2
- IMPACT | c.41A>C p.E14A | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52423826; called by muse, varscan2
- IMPG1 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64055196; called by muse, mutect2, varscan2
- INTS7 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV65345698; called by muse, mutect2, varscan2
- IRAK1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1186579541, COSV64113842; called by muse, mutect2, varscan2
- IRF6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 108/320 reads (34%) | catalogued as COSV65420641; called by muse, mutect2, varscan2
- ISL1 | c.260G>C p.S87T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV57935986; called by muse, mutect2, varscan2
- JADE3 | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54471584; called by muse, mutect2, varscan2
- KCNMB3 | c.36T>G p.H12Q | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV58571836; called by muse, mutect2, varscan2
- KMT2C | c.4349A>G p.D1450G | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51516547; called by muse, mutect2, varscan2
- KRT81 | c.886T>C p.W296R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59811728; called by muse, mutect2, varscan2
- LAMP3 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 91/1298 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs150380664; called by muse, mutect2
- LCE3A | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV59551239; called by muse, mutect2, varscan2
- LHFPL5 | c.630C>A p.D210E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV64178830; called by muse, mutect2, varscan2
- LRP1B | c.12938C>A p.P4313Q | Missense Mutation (SNP) | VAF 280/863 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV101254409, COSV67280348; called by muse, mutect2, varscan2
- LRP2 | c.4498A>G p.R1500G | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs777314724, COSV55579530; called by muse, mutect2, varscan2
- LRRK2 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54175503; called by muse, mutect2, varscan2
- MAGI2 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV62687638; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV61010785; called by muse, mutect2, varscan2
- MC3R | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54765293; called by muse, mutect2, varscan2
- MED12 | c.4120-1G>T p.X1374_splice | Splice Site (SNP) | VAF 95/469 reads (20%) | catalogued as COSV61359293; called by muse, mutect2, varscan2
- MED12 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 95/466 reads (20%) | catalogued as COSV61359301; called by muse, mutect2, varscan2
- MEF2D | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 53/148 reads (36%) | catalogued as COSV61730570; called by muse, mutect2, varscan2
- MEGF6 | c.267-1G>T p.X89_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV62994887; called by muse, mutect2
- MTHFD1L | c.2029G>C p.V677L | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66227845; called by muse, mutect2, varscan2
- MYB | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57202787; called by muse, mutect2, varscan2
- NBAS | c.2016C>T p.S672= | Splice Region (SNP) | VAF 38/106 reads (36%) | catalogued as COSV55741477; called by muse, mutect2, varscan2
- NCK1 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 255/1558 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs773408330, COSV56639032; called by muse, mutect2, varscan2
- NEUROD6 | c.640C>G p.P214A | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as COSV51773785; called by muse, mutect2, varscan2
- NHS | c.3274C>T p.H1092Y | Missense Mutation (SNP) | VAF 162/541 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV66274792; called by muse, mutect2, varscan2
- NKAPL | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV59199711; called by muse, mutect2, varscan2
- NUP210L | c.2850+2T>A p.X950_splice | Splice Site (SNP) | VAF 77/256 reads (30%) | catalogued as COSV55159019; called by muse, mutect2, varscan2
- OCRL | c.2329C>A p.P777T | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.516); catalogued as COSV63982233; called by muse, mutect2, varscan2
- OR13G1 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV62945416; called by muse, mutect2, varscan2
- OTOL1 | c.1418C>A p.S473Y | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); catalogued as COSV60008863; called by muse, mutect2, varscan2
- PAOX | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1472318687, COSV53371964; called by muse, mutect2, varscan2
- PCDH11X | c.541-1G>T p.X181_splice | Splice Site (SNP) | VAF 30/123 reads (24%) | catalogued as COSV53514124; called by muse, mutect2, varscan2
- PCK1 | c.865G>T p.G289W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60130976, COSV60131680; called by muse, mutect2, varscan2
- PKDREJ | c.3967C>T p.H1323Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV53554172; called by muse, mutect2, varscan2
- PLCB2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV53039081; called by muse, mutect2, varscan2
- PPM1B | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56770369; called by muse, mutect2, varscan2
- PPP1R3F | c.1772A>C p.E591A | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV50020857; called by muse, mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 12/97 reads (12%) | catalogued as rs756557178; called by mutect2, varscan2
- RERE | c.386A>T p.D129V | Missense Mutation (SNP) | VAF 280/831 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61938407, COSV61952139; called by muse, mutect2, varscan2
- RHBDL2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56710235; called by muse, mutect2, varscan2
- RHOH | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67807378; called by muse, mutect2, varscan2
- RNF20 | c.1943A>T p.D648V | Missense Mutation (SNP) | VAF 220/400 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66662532; called by muse, mutect2, varscan2
- RNF213 | c.2510A>G p.E837G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV60631610; called by muse, mutect2, varscan2
- RP1 | c.1325C>A p.A442E | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs755794081, COSV55129224; called by muse, mutect2, varscan2
- RPS6KC1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 101/321 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65303424; called by muse, mutect2, varscan2
- RTL9 | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 538/2317 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV71826535; called by muse, mutect2, varscan2
- RTTN | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776126193, COSV55341618; called by muse, mutect2, varscan2
- RUBCNL | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV59795377; called by muse, mutect2, varscan2
- RXFP1 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV57058080; called by muse, mutect2, varscan2
- SELENOP | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV62794386; called by muse, mutect2, varscan2
- SEMA4C | c.2330A>T p.H777L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59692701; called by muse, mutect2, varscan2
- SERINC4 | c.893T>A p.I298N | Missense Mutation (SNP) | VAF 99/453 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV51052203; called by muse, mutect2, varscan2
- SERPINB11 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV66958006; called by muse, mutect2, varscan2
- SGSM1 | c.1652T>A p.F551Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV68514405; called by muse, mutect2, varscan2
- SLC10A7 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53891991; called by muse, mutect2, varscan2
- SLC35F1 | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV64511483; called by muse, mutect2, varscan2
- SLC9A6 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV65789256; called by muse, mutect2, varscan2
- SNX32 | c.1117A>C p.N373H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57450763; called by muse, mutect2, varscan2
- SON | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV51671712; called by muse, mutect2, varscan2
- TMEM101 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780876294, COSV52814337; called by muse, mutect2, varscan2
- TMEM132D | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV67163137; called by muse, mutect2, varscan2
- TNKS1BP1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV64103085; called by muse, mutect2, varscan2
- TRPM8 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV61224631; called by muse, mutect2, varscan2
- TRPV5 | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.279); catalogued as rs1224508560, COSV54690896; called by muse, mutect2, varscan2
- TTC21A | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV57189898; called by muse, mutect2, varscan2
- TUBB4A | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV51168574; called by muse, mutect2, varscan2
- TYK2 | c.3309C>A p.S1103R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53385889; called by muse, varscan2
- VPS13C | c.2487G>T p.M829I (on ENST00000644861 / NM_020821.3; = p.M786I on NM_017684.5) | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51429490; called by muse, mutect2, varscan2
- VPS13D | c.9437G>T p.C3146F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV50621385; called by muse, mutect2, varscan2
- WNK3 | c.1463T>C p.V488A | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63616372; called by muse, mutect2, varscan2
- WNT2B | c.802C>T p.R268C (on ENST00000369684 / NM_024494.3; = p.R249C on NM_004185.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs761702933, COSV56674751, COSV56676043; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1465G>C p.V489L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV54302284; called by muse, mutect2, varscan2
- ZNF101 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV58910183; called by muse, mutect2, varscan2
- ZNF460 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV64416686; called by muse, mutect2, varscan2
- ZNF543 | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58629606; called by muse, mutect2, varscan2
- ZNF57 | c.621T>A p.H207Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV60984992; called by muse, mutect2, varscan2
- ZNF676 | c.273A>G p.I91M (on ENST00000650058; = p.I59M on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV68095341; called by muse, mutect2, varscan2
- ZNF761 | c.1288A>T p.K430* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as COSV61889695; called by muse, mutect2, varscan2
- ZNF804A | c.2966C>A p.T989N | Missense Mutation (SNP) | VAF 137/443 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs764514125, COSV56474023; called by muse, mutect2, varscan2
- ADGRB3 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- AGAP4 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 51/433 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CAGE1 | c.716dup p.N239Kfs*7 (on ENST00000512086; = p.N103Kfs*7 on NM_205864.3) | Frame Shift Ins (INS) | VAF 42/170 reads (25%) | called by mutect2, pindel, varscan2
- CHD7 | c.1412dup p.L471Ffs*104 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- NEGR1 | c.369_371del p.Q123del | In Frame Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- OR2F2 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 23/835 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLQ | c.2138del p.M713Rfs*14 | Frame Shift Del (DEL) | VAF 76/507 reads (15%) | called by mutect2, pindel, varscan2
- SYNPO2 | c.3300del p.I1101Ffs*22 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | called by mutect2, pindel, varscan2
- TRIM48 | c.589del p.V197Cfs*9 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel
- TYK2 | c.3315del p.T1106Rfs*7 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by pindel, varscan2
- ADAM2 | c.1893G>A p.K631= | Silent (SNP) | VAF 77/208 reads (37%) | catalogued as COSV55869158; called by muse, mutect2, varscan2
- AFTPH | c.819G>T p.L273= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV53216154, COSV53222778; called by muse, mutect2, varscan2
- AHNAK | c.14358C>G p.P4786= | Silent (SNP) | VAF 234/843 reads (28%) | catalogued as COSV57235289; called by muse, mutect2, varscan2
- ALPK3 | c.2832G>T p.G944= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV51941734; called by muse, mutect2, varscan2
- BRWD3 | c.810A>T p.I270= | Silent (SNP) | VAF 122/456 reads (27%) | catalogued as COSV64754586; called by muse, mutect2, varscan2
- CCL20 | c.51A>C p.L17= | Silent (SNP) | VAF 135/456 reads (30%) | catalogued as COSV62591827; called by muse, mutect2, varscan2
- CEACAM5 | c.879T>C p.N293= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as COSV55756039; called by muse, mutect2, varscan2
- COL4A5 | c.3165C>T p.S1055= | Silent (SNP) | VAF 54/288 reads (19%) | catalogued as COSV60373006, COSV60374636; called by muse, mutect2, varscan2
- CRISP3 | c.765C>T p.T255= (on ENST00000371159 / NM_001368123.1; = p.T237= on NM_006061.4) | Silent (SNP) | VAF 55/218 reads (25%) | catalogued as COSV53823598; called by muse, mutect2, varscan2
- CWF19L2 | c.1464G>T p.L488= | Silent (SNP) | VAF 92/329 reads (28%) | catalogued as COSV56508281, COSV56521931; called by muse, mutect2, varscan2
- DCC | c.1671A>T p.P557= | Silent (SNP) | VAF 132/409 reads (32%) | catalogued as COSV59144685; called by muse, mutect2, varscan2
- ERBB4 | c.3087C>T p.N1029= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV61531510; called by muse, mutect2, varscan2
- FAT4 | c.594G>T p.A198= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV67891190, COSV67901864; called by muse, mutect2, varscan2
- FBXO40 | c.24G>T p.P8= | Silent (SNP) | VAF 193/389 reads (50%) | catalogued as COSV57522997, COSV57528285; called by muse, mutect2, varscan2
- FIGN | c.1152C>T p.S384= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as rs762282252, COSV60772814; called by muse, mutect2, varscan2
- GRIN2B | c.3825C>T p.N1275= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs200571186, COSV74204684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H1-2 | c.441G>A p.P147= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV59192137, COSV59193598; called by muse, mutect2, varscan2
- HLA-DMB | c.366C>A p.T122= | Silent (SNP) | VAF 203/716 reads (28%) | catalogued as COSV66870651, COSV66870991; called by muse, mutect2, varscan2
- HMBOX1 | c.390A>G p.G130= | Silent (SNP) | VAF 65/193 reads (34%) | catalogued as COSV55072903; called by muse, mutect2, varscan2
- HUWE1 | c.6429G>T p.G2143= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV53367724; called by muse, mutect2, varscan2
- IGHV3-30 | c.132T>C p.S44= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs760862789; called by muse, mutect2, varscan2
- IMPG2 | c.2832G>T p.T944= | Silent (SNP) | VAF 393/649 reads (61%) | catalogued as COSV51975531; called by muse, mutect2, varscan2
- ISL1 | c.189G>A p.G63= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs777485181, COSV57936215; called by muse, mutect2, varscan2
- LRRC30 | c.363C>G p.V121= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV67302410; called by muse, mutect2, varscan2
- NOP14 | c.1935G>A p.S645= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs778767912, COSV58628238; called by muse, mutect2, varscan2
- PUS1 | c.1269C>T p.D423= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs531516145, COSV59036898; called by muse, mutect2, varscan2
- SEMA4C | c.2331C>T p.H777= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs200526785, COSV59692693; called by muse, mutect2, varscan2
- SEMG1 | c.390T>C p.H130= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as rs1474784120, COSV54875015; called by muse, mutect2, varscan2
- SERPINA12 | c.78A>G p.S26= | Silent (SNP) | VAF 91/201 reads (45%) | catalogued as COSV57946550; called by muse, mutect2, varscan2
- SPATA31E1 | c.744G>A p.P248= | Silent (SNP) | VAF 32/279 reads (11%) | catalogued as rs370494405, COSV57793610, COSV57796058; called by muse, mutect2, varscan2
- SPTLC3 | c.798T>C p.G266= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as rs771123243, COSV65469325; called by muse, mutect2, varscan2
- TENM1 | c.3780C>A p.V1260= | Silent (SNP) | VAF 298/662 reads (45%) | catalogued as COSV64445359; called by muse, mutect2, varscan2
- TENM3 | c.3435C>A p.V1145= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV69312553, COSV69322301; called by muse, mutect2, varscan2
- TERT | c.2160C>A p.I720= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV57245576; called by muse, mutect2, varscan2
- TMPRSS15 | c.600T>A p.A200= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as COSV53051458; called by muse, mutect2, varscan2
- TRPC5 | c.1923T>C p.F641= | Silent (SNP) | VAF 90/420 reads (21%) | catalogued as COSV53305115; called by muse, mutect2, varscan2
- UVSSA | c.2091C>T p.H697= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs529975173, COSV66231168; called by muse, mutect2, varscan2
- ZNF442 | c.840T>C p.Y280= | Silent (SNP) | VAF 116/336 reads (35%) | catalogued as COSV54423726; called by muse, mutect2, varscan2
- ZNF676 | c.1659T>A p.T553= (on ENST00000650058; = p.T521= on NM_001001411.3) | Silent (SNP) | VAF 61/180 reads (34%) | catalogued as COSV68095200; called by muse, mutect2, varscan2
- ZNF93 | c.1398A>T p.S466= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as rs559404029, COSV59373804; called by muse, varscan2
- PRB1 | c.101-542G>A | Intron (SNP) | VAF 285/944 reads (30%) | catalogued as COSV53707208; called by muse, mutect2, varscan2
